TCGA case TCGA-EM-A3O3 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: University Health Network. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2a398af1-aea5-4aae-ab00-a2dc152f965a

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 83 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 83.5 years (30,500 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N1a; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 441 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 16; Measurement unit: Centimeters; Tumor depth measurement: 1.4; Tumor length measurement: 3.1; Tumor width measurement: 2.7.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 151 days; Days to treatment end: 151 days; Treatment dose: 100 mCi; Treatment outcome: Complete Response; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 100; Pretreatment: rhTSH; Timepoint category: First Treatment.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 100; Pretreatment: rhTSH.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.

Follow-up (3 entries)
- Days to follow up: 224 days; Disease response: Tumor Free.
- Imaging type: CT Scan; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 441.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Lymphocytic Thyroiditis.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EM-A3O3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-EM-A3O3-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-EM-A3O3-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EM-A3O3-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No; New tumor event diagnosis indicator: No.
- Patient personal medical history thyroid gland disorder names: History thyroid disease: Lymphocytic Thyroiditis.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: CT with contrast.
- Follow-up form: Lost to follow-up: No; I 131 radiation first treatment method: rhTSH; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 441 days; disease-specific survival: no event (censored), 441 days; disease-free interval: no event (censored), 441 days; progression-free interval: no event (censored), 441 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EM-A3O3-01A-11D-A21Y-01): tumor purity 0.65, ploidy 2.04, whole-genome doublings 0.
